Somatic mutation profile of tumor specimen TCGA-DK-A3WY-01A (aliquot TCGA-DK-A3WY-01A-11D-A22Z-08) from TCGA case TCGA-DK-A3WY, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,536 days).
Specimen TCGA-DK-A3WY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb1e2999-0200-4511-a36d-f1ab4c549084.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3WY-10A (Blood Derived Normal), aliquot TCGA-DK-A3WY-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29710bf9-14eb-4df6-bc59-24a5a612b4ac

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Nonsense Mutation 3, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.4208G>C p.G1403A | Missense Mutation (SNP) | VAF 5/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201104; called by muse, mutect2
- ANXA13 | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 8/224 reads (4%) | catalogued as COSV99146068; called by muse, mutect2
- CISH | c.103C>T p.Q35* (on ENST00000348721 / NM_145071.4; = p.Q52* on NM_013324.6) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100811757; called by muse, varscan2
- ECI2 | c.1118G>A p.G373E (on ENST00000380118 / NM_206836.3; = p.G343E on NM_006117.2) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60985311; called by muse, mutect2
- GPR87 | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.748); catalogued as COSV53462395; called by muse, mutect2
- GPR87 | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53462411; called by muse, mutect2
- KL | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV66308031; called by muse, mutect2
- PHF19 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV65878363; called by muse, mutect2
- SH2D1B | c.229C>G p.P77A | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV63392018; called by muse, mutect2
- SOS1 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV67673973, COSV67674055; called by muse, mutect2
- SPTAN1 | c.4645G>T p.E1549* | Nonsense Mutation (SNP) | VAF 6/95 reads (6%) | catalogued as COSV63990551; called by muse, mutect2
- ZP2 | c.1833C>T p.V611= | Splice Region (SNP) | VAF 4/52 reads (8%) | catalogued as COSV54812630; called by muse, mutect2
- CFAP69 | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM5 | c.2342G>C p.G781A | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- FAM83C | c.276C>T p.S92= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs758914035, COSV65582243; called by muse, mutect2, varscan2
- GCDH | c.198C>T p.L66= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as rs1320241434, COSV99322369; called by muse, mutect2
